Surgical pathology report (de-identified scan), TCGA case TCGA-G8-6326, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Roswell Park, specimen TCGA-G8-6326-01A (Primary Tumor).

[page 1 of 3]
SPECIMENS:

- A. OMENTAL BIOPSY
- B. MESENTERIC NODULES

TCGA-G8-6326

AMENDMENT REASON

This case was originally signed out [REDACTED] and is being amended to remove a duplicate "" suffix entry to patient name which was entered incorrectly during registration. No other changes were made to this report.

SPECIMEN(S):

- A. OMENTAL BIOPSY
- B. MESENTERIC NODULES

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA and TPA. Omental biopsy: Suspicious for lymphoma (workup on permanent section will be done) called by [REDACTED]

GROSS DESCRIPTION:

A. OMENTAL BIOPSY

Received fresh is a piece of fatty tissue measuring 13 x 8 x 3 cm. The specimen has firm, diffuse areas of tan discoloration ranging in size from 0.5 to 1.8 cm. A section of the area of discoloration is submitted for frozen section diagnosis. Representative sections are submitted in FSA1 (frozen section), A2-A4 (formalin fixed sections), and A5 (B5 fixed section).

B. MESENTERIC NODULES

Received fresh is an aggregate of firm tan tissue measuring 3 x 2.2 x 1 cm. Touch preparations are done. Portions of tissue are submitted to cytogenetics, FCM surface markers, snap freezing for possible future diagnostic studies, and tissue procurement. The rest of tissue is submitted entirely in B1-B2 (formalin fixed sections) and B3 (B5 fixed sections).

DIAGNOSIS:

A. OMENTUM, NODULES, EXCISION:

- LARGE PLEOMORPHIC B-LINAGE LYMPHOMA MOST CONSISTENT WITH T-CELL/HISTIOCYTE-RICH LARGE B-CELL LYMPHOMA (SEE NOTE)

B. MESENTERY, NODULES, EXCISION:

- LARGE PLEOMORPHIC B-LINAGE LYMPHOMA MOST CONSISTENT WITH T-CELL/HISTIOCYTE-RICH LARGE B-CELL LYMPHOMA (SEE NOTE)

NOTE: The differential includes T-cell/histiocyte-rich large B-cell lymphoma, classical Hodgkin lymphoma, versus, anaplastic large cell lymphoma. The T-cell/histiocyte-rich large B-cell lymphoma is favored based on the expressing of B-lineage specific markers (CD20, CD79a, and PAX5), CD45, and BCL6 and lacking of CD15, CD30, and EBER expression by the large lymphoma cells.

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Intra-abdominal lymphadenopathy

MICROSCOPIC DESCRIPTION:

There are sparse scattered pleomorphic Reed-Sternberg-like large cells in a background of numerous T cells and histiocytes without plasma cell or eosinophilic infiltration. In-situ hybridization staining for EBV encoded-RNA (EBER) performed on block# B2. EBER is negative. Immunoperoxidase stains are performed on tissue sections of block# A3, A5, B1, and B3. The results are summarized in the following table.

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block A3

Population: The large lymphoma cells

[page 2 of 3]
Stain/Marker:Result: Comment:

CD 30 Negative

CD 15 NegativeFromalin-fixed tissue

PERFORIN NegativeSmall proportion of the lymphoma large cells probably are positive with cytoplasmic granular staining

Material: Block A5

Population: The large lymphoma cells

Stain/Marker:Result: Comment:

CD 15 NegativeB5-fixed tissue

Material: Block B1

Population: The large lymphoma cells

Stain/Marker:Result: Comment:

CD 30 Negative

CD 15 Negative

CD 3 NegativeThe vast majority of the background cells are T cells

CD 45 Positive Most of the lymphoma cells are strongly positive

CD23 NegativeNo follicular dendritic cell networks are seen

CD 10 Negative

ALK-1 Negative

CD 7 NegativeSimilar to Cd3

CD4 NegativeT cels and histiocytes are positive

CD8 NegativeProportion of T cells are positive

CD56 NegativeRare lymphoid cells are positive

CD 43, LEU 22, MT1 NegativeT cells and histiocytes are positive

TIA-1 NegativeNumerous cytotoxic lymphoid cells are positive

GRANZYME B NegativeNumerous cytotoxic lymphoid cells are positive

PAX-5 Positive Strong staining intensity. Paucity of small B cells are seen

CD5 NegativeSimilar to CD3

CD57-LEU7 NegativeNumerous activated T/NK cells are seen with occusional rosettes formation around the large lymphoma cells

CD79A Positive Paucity of small B cells are seen

MUM-1 Negative

PERFORIN NegativeNo positive lymphoma cells are seen in this tissue section

CD2 NegativeSimilar to CD3

CD123 Negative

CD45RA-MT2 NegativeFew background cells are positive

UCHL-1, CD 45 RO NegativeSimilar to CD3

BF1 NegativeSimilar to CD3

BCL-6 Positive Strong staining intensity

CD21 NegativeNo follicular dendritic cell networks are seen

CD68 NegativeNumerous background histiocytes are positive

CD 20, L26 50 % Positive Cells Strong staining density. Paucity of small B cells are seen

EMA Negative

Material: Block B3

Population: The large lymphoma cells

Stain/Marker:Result: Comment:

CD 15 NegativeB5 fixed tissue

[page 3 of 3]
The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the Immunohistochemistry Laboratory of the. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Special stains and/or immunohistochemical stains were performed with appropriately stained positive and negative controls.

FLOW CYTOMETRY:

Flow cytometry, "limited mainly B-cell panel" performed on tissue submitted from this lymph node, shows predominantly CD3+ T cells (86% of total cells) and rare B cells without definite evidence of monotypic B cell neoplasm. See separate report.

CONVENTIONAL CYTOGENETICS/FISH:

Conventional cytogenetics, performed on tissue submitted from this lymph node, is pending.

Source: NCI Genomic Data Commons file d939e77e-738e-4533-8ce8-3f699564abb8 (TCGA-G8-6326.3E506666-5CEF-4416-9C02-1DF6982B4ED1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).